Somatic mutation profile of tumor specimen TCGA-TM-A84I-01A (aliquot TCGA-TM-A84I-01A-11D-A36O-08) from TCGA case TCGA-TM-A84I, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 30.7 years (11,221 days).
Specimen TCGA-TM-A84I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5190f848-6d8a-4755-9070-3a32de567221.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TM-A84I-10A (Blood Derived Normal), aliquot TCGA-TM-A84I-10A-01D-A367-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/924c6ae7-0748-48bc-8efe-567b8dfc70f8

The open-access MAF lists 29 somatic variants for this specimen: 25 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 23, Silent 4, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 36/71 reads (51%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 20/34 reads (59%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 34/73 reads (47%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACOXL | c.564C>A p.D188E | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100490602; called by muse, mutect2, varscan2
- AQP7 | c.569C>T p.T190M | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.137); catalogued as rs755227850, COSV99953604; called by muse, mutect2, varscan2
- ASIC3 | c.915C>A p.S305R | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV99877342; called by muse, mutect2
- CD163L1 | c.3874G>T p.A1292S | Missense Mutation (SNP) | VAF 6/141 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100550610; called by muse, mutect2
- CYP2A13 | c.1451C>A p.P484Q | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100386997, COSV57839888; called by muse, mutect2, varscan2
- DPT | c.146A>G p.Q49R | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.367); catalogued as rs919049121, COSV100892174, COSV63189859; called by muse, mutect2
- GALNT1 | c.259A>G p.M87V | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.011); catalogued as rs1429588681, COSV99322486; called by muse, mutect2, varscan2
- H2AC16 | c.53G>C p.R18P | Missense Mutation (SNP) | VAF 57/117 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.867); catalogued as COSV58900278, COSV58900742; called by muse, mutect2, varscan2
- LRP2 | c.2183C>A p.T728N | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.272); catalogued as COSV99790043; called by muse, mutect2, varscan2
- MRTFB | c.1280T>C p.I427T | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1304569812, COSV100371786; called by muse, mutect2, varscan2
- NUP153 | c.659A>G p.Q220R | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV100020159; called by muse, mutect2, varscan2
- NXF3 | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs778895565, COSV101222074; called by muse, mutect2, varscan2
- OR2A5 | c.516T>A p.H172Q | Missense Mutation (SNP) | VAF 45/238 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101278839; called by muse, mutect2, varscan2
- PPP2R5B | c.1106C>T p.P369L | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV99376388; called by muse, mutect2, varscan2
- RASSF6 | c.1025T>C p.I342T (on ENST00000342081 / NM_201431.2; = p.I310T on NM_177532.5) | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV100275169; called by muse, mutect2
- SH3TC2 | c.1946A>G p.H649R | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT tolerated (0.19); PolyPhen benign (0.065); catalogued as rs760422780, COSV100102294; called by muse, mutect2, varscan2
- TEK | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV101193548, COSV66231813; called by muse, mutect2, varscan2
- THUMPD3 | c.359T>C p.L120S | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV100560754; called by muse, mutect2, varscan2
- VPS13B | c.4793G>A p.R1598K | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100663416; called by muse, mutect2, varscan2
- ZDHHC11 | c.599G>T p.G200V | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.074); catalogued as COSV99363524; called by mutect2, varscan2
- ATRX | c.3904_3907del p.R1302Lfs*43 | Frame Shift Del (DEL) | VAF 65/70 reads (93%) | called by mutect2, pindel, varscan2
- S100A7A | c.244_248del p.I82Rfs*? (on ENST00000329256; = p.I82Rfs*50 on NM_176823.4) | Frame Shift Del (DEL) | VAF 21/57 reads (37%) | called by mutect2, pindel, varscan2
- ALOX15 | c.933C>T p.L311= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as COSV99541732; called by muse, mutect2, varscan2
- LRP1 | c.1611C>T p.I537= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as COSV99677043; called by muse, mutect2, varscan2
- RIMBP2 | c.2103C>T p.Y701= | Silent (SNP) | VAF 20/40 reads (50%) | catalogued as rs574899300, COSV55472368; called by muse, mutect2, varscan2
- SCNN1A | c.1677C>T p.F559= | Silent (SNP) | VAF 34/101 reads (34%) | catalogued as rs762582819, COSV57436127; called by muse, mutect2, varscan2
